MMRF case MMRF_1242 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/917a7c76-8206-4204-a834-00ca88da38ef

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 610 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,392 days); ISS stage: II; Days to last known disease status: 610 days (1.7 years); Days to last follow up: 610 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 72 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 233 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 302 days; Days to treatment end: 303 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 305 days; Days to treatment end: 305 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 386 days (1.1 years); Days to treatment end: 540 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 610.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 8 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.707 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.69 mg/dL; Immunoglobulin G 30 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.61 ×10⁹/L; Platelets 397 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 1.98 mmol/L; Albumin 23 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 85 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.59 ×10⁹/L; Platelets 449 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 28 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 169 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.56 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 281 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 4.46 mmol/L.
- Day 372 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.28 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.43 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 470 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.18 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.45 mmol/L.
- Day 554 (ECOG 1): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 41.7 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 7.42 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.95 mmol/L; Albumin 37 g/L; Total Protein 9.6 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day 8: Weight: 46 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (4 samples)
- Sample MMRF_1242_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 8 days.
- Sample MMRF_1242_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 8 days.
- Sample MMRF_1242_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 372 days (1.0 years).
- Sample MMRF_1242_5_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 554 days (1.5 years).
